Somatic mutation profile of cancer-model specimen HCM-WCMC-1359-C34-85A (3D Organoid; aliquot HCM-WCMC-1359-C34-85A-01D-A937-36), derived from the primary tumor of HCMI case HCM-WCMC-1359-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 60.5 years (22,094 days).
Specimen HCM-WCMC-1359-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c02b4bb-21ed-498c-a414-15b080bdc8bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1359-C34-10A (Blood Derived Normal), aliquot HCM-WCMC-1359-C34-10A-01D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fab26893-0d15-4849-8c98-d44c7e68058b

The open-access MAF lists 192 somatic variants for this specimen: 135 protein-altering or splice-affecting, 49 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 49, Nonsense Mutation 11, Intron 5, Frame Shift Del 3, In Frame Del 2, 5'Flank 1, Nonstop Mutation 1, 3'UTR 1, Splice Site 1, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 382/383 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB6 | c.1840A>T p.M614L | Missense Mutation (SNP) | VAF 304/584 reads (52%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99202481; called by muse, mutect2, varscan2
- ADAM12 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 295/441 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64107034; called by muse, mutect2, varscan2
- ADAMTS19 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 205/469 reads (44%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV99184486; called by muse, mutect2, varscan2
- ADAMTS20 | c.2317C>G p.L773V | Missense Mutation (SNP) | VAF 133/294 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as COSV101166293; called by muse, mutect2, varscan2
- AGTPBP1 | c.1565C>T p.S522L (on ENST00000357081 / NM_001330701.2; = p.S482L on NM_015239.2) | Missense Mutation (SNP) | VAF 136/394 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1420730699; called by muse, mutect2, varscan2
- ANKRD11 | c.6005C>T p.S2002F | Missense Mutation (SNP) | VAF 213/749 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV99039934; called by muse, mutect2, varscan2
- ANKRD30B | c.3806G>T p.C1269F | Missense Mutation (SNP) | VAF 34/540 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs1300045879; called by muse, mutect2
- ASB16 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 244/245 reads (100%) | catalogued as rs780082937; called by muse, mutect2, varscan2
- ASTN2 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 268/400 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as rs764391655; called by muse, varscan2
- BAHCC1 | c.3733G>A p.E1245K | Missense Mutation (SNP) | VAF 439/833 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.06); catalogued as rs782392409; called by muse, mutect2, varscan2
- BRD8 | c.3416G>A p.G1139E | Missense Mutation (SNP) | VAF 144/586 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs142953765; called by muse, mutect2, varscan2
- CASP5 | c.770C>G p.S257C | Missense Mutation (SNP) | VAF 291/450 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755827751; called by muse, mutect2, varscan2
- CD248 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 51/899 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs551979045; called by muse, mutect2
- CDKN2A | c.131dup p.Y44* | Nonsense Mutation (INS) | VAF 136/189 reads (72%) | catalogued as rs730881673; called by mutect2, pindel, varscan2
- CELSR3 | c.9250C>T p.R3084* | Nonsense Mutation (SNP) | VAF 320/677 reads (47%) | catalogued as rs759724759, COSV99373332; called by muse, mutect2, varscan2
- CXCL16 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 438/439 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as COSV53411780; called by muse, mutect2, varscan2
- DCAF12L2 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 206/436 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs140058006, COSV63583145; called by muse, varscan2
- DCAF4L1 | c.1104C>A p.F368L | Missense Mutation (SNP) | VAF 241/370 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); catalogued as COSV60786749; called by muse, mutect2, varscan2
- DNAJB5 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 330/484 reads (68%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as rs761475982; called by muse, mutect2, varscan2
- ERBB2 | c.3458G>A p.R1153Q | Missense Mutation (SNP) | VAF 405/832 reads (49%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs758365405, COSV54066593; called by muse, mutect2, varscan2
- FAM171A1 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 240/604 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs765007765; called by muse, mutect2, varscan2
- FAT3 | c.9739G>A p.E3247K | Missense Mutation (SNP) | VAF 112/327 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs186585296; called by muse, mutect2, varscan2
- FLNC | c.4274G>T p.G1425V | Missense Mutation (SNP) | VAF 436/615 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57949464; called by muse, mutect2, varscan2
- GTF3C3 | c.755G>C p.R252P | Missense Mutation (SNP) | VAF 18/551 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV55831200; called by muse, mutect2
- H2AX | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 188/606 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99598061, COSV99598297; called by muse, mutect2, varscan2
- H2BC4 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 79/303 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV100020125; called by muse, mutect2, varscan2
- HGS | c.1618_1620del p.E540del | In Frame Del (DEL) | VAF 80/929 reads (9%) | catalogued as rs780049476; called by mutect2, pindel
- HJURP | c.2013_2024del p.G672_D675del | In Frame Del (DEL) | VAF 232/503 reads (46%) | catalogued as rs767162725; called by mutect2, varscan2
- IVL | c.1469T>C p.L490P | Missense Mutation (SNP) | VAF 220/840 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.66); catalogued as rs985873590, COSV100908321; called by muse, mutect2
- KCNH3 | c.770C>A p.A257D | Missense Mutation (SNP) | VAF 319/638 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV99235234; called by muse, mutect2, varscan2
- LHFPL3 | c.56C>G p.S19W | Missense Mutation (SNP) | VAF 277/782 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV67809950; called by muse, mutect2, varscan2
- LRRC9 | c.2197G>T p.D733Y | Missense Mutation (SNP) | VAF 103/192 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355598297; called by muse, mutect2, varscan2
- MED12L | c.1364C>G p.T455S | Missense Mutation (SNP) | VAF 218/487 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.848); catalogued as COSV56387477; called by muse, mutect2
- MEGF11 | c.63C>A p.N21K | Missense Mutation (SNP) | VAF 136/500 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs754531839; called by muse, mutect2, varscan2
- NCAM2 | c.1729C>G p.Q577E | Missense Mutation (SNP) | VAF 21/425 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.26); catalogued as COSV53099778; called by muse, mutect2
- NHLRC4 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 214/664 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV50323671; called by muse, mutect2
- OBSCN | c.8717C>T p.T2906I | Missense Mutation (SNP) | VAF 127/509 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as rs933866975; called by muse, mutect2, varscan2
- OR6C76 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 143/327 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as COSV60389640; called by muse, mutect2, varscan2
- PLEKHG6 | c.992G>C p.R331P | Missense Mutation (SNP) | VAF 264/548 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs370748302; called by muse, mutect2, varscan2
- PTCHD4 | c.2435C>A p.P812H | Missense Mutation (SNP) | VAF 295/450 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59776858, COSV59798131; called by muse, mutect2, varscan2
- RCSD1 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 109/461 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV63259595; called by muse, mutect2, varscan2
- RNF216 | c.2524G>A p.D842N (on ENST00000425013 / NM_207116.3; = p.D899N on NM_207111.4) | Missense Mutation (SNP) | VAF 432/860 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV66288812; called by muse, mutect2, varscan2
- RNF43 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 393/735 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV68457329; called by muse, mutect2, varscan2
- RP1L1 | c.5968G>C p.E1990Q | Missense Mutation (SNP) | VAF 352/778 reads (45%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.734); catalogued as COSV66758181; called by muse, mutect2, varscan2
- SHOC2 | c.1456C>G p.L486V | Missense Mutation (SNP) | VAF 148/262 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs767570209, COSV54621772; called by muse, mutect2, varscan2
- SLC22A16 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 89/236 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1342872863, COSV100397965; called by muse, mutect2, varscan2
- SLC24A3 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 149/326 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as rs1286917670; called by muse, varscan2
- SLC44A3 | c.373C>T p.L125F (on ENST00000271227 / NM_001114106.3; = p.L77F on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 262/405 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99598482; called by muse, mutect2, varscan2
- SPACA1 | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 78/267 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as COSV52759079; called by muse, mutect2, varscan2
- STK11 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 365/367 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100479383, COSV58820651; called by muse, mutect2, varscan2
- TIAM1 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 342/699 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV54558946; called by muse, mutect2, varscan2
- ACOX3 | c.460G>C p.G154R | Missense Mutation (SNP) | VAF 111/323 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AMPD2 | c.1165G>T p.E389* | Nonsense Mutation (SNP) | VAF 144/393 reads (37%) | called by muse, mutect2, varscan2
- ASH1L | c.5191G>C p.E1731Q | Missense Mutation (SNP) | VAF 121/531 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ASPSCR1 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 214/481 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP5F1A | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 234/517 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B3GNT8 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 18/409 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.204); called by muse, mutect2
- BLM | c.2343G>C p.E781D | Missense Mutation (SNP) | VAF 236/362 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- BTNL9 | c.110-1G>T p.X37_splice | Splice Site (SNP) | VAF 145/345 reads (42%) | called by muse, mutect2, varscan2
- C8B | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 302/440 reads (69%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CHPF2 | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 755/1059 reads (71%) | called by muse, mutect2, varscan2
- CIT | c.3297G>C p.E1099D | Missense Mutation (SNP) | VAF 273/545 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- COL25A1 | c.862G>C p.G288R | Missense Mutation (SNP) | VAF 100/302 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COX5B | c.389G>T p.*130Lext*20 | Nonstop Mutation (SNP) | VAF 216/480 reads (45%) | called by muse, varscan2
- CRELD1 | c.1067C>G p.S356* | Nonsense Mutation (SNP) | VAF 234/451 reads (52%) | called by muse, varscan2
- CRELD1 | c.1071G>C p.E357D | Missense Mutation (SNP) | VAF 225/468 reads (48%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, varscan2
- CRELD1 | c.1217C>G p.S406* | Nonsense Mutation (SNP) | VAF 276/565 reads (49%) | called by muse, varscan2
- CX3CL1 | c.756G>C p.Q252H | Missense Mutation (SNP) | VAF 207/602 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- DCAF1 | c.3535G>A p.D1179N | Missense Mutation (SNP) | VAF 128/283 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DHX30 | c.1099G>C p.V367L (on ENST00000445061 / NM_138615.3; = p.V328L on NM_014966.3) | Missense Mutation (SNP) | VAF 190/400 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK6 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 340/342 reads (99%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- DUSP8 | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 366/581 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM184A | c.2151A>T p.Q717H | Missense Mutation (SNP) | VAF 193/302 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FAM53B | c.10G>C p.V4L | Missense Mutation (SNP) | VAF 164/491 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FCHO2 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2
- FSIP2 | c.2145A>G p.I715M | Missense Mutation (SNP) | VAF 266/567 reads (47%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- HPN | c.1058G>C p.S353T | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HS3ST2 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 446/644 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2
- IL12B | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 295/642 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INSRR | c.3634G>T p.E1212* | Nonsense Mutation (SNP) | VAF 100/728 reads (14%) | called by mutect2, varscan2
- IVNS1ABP | c.770del p.K257Sfs*11 | Frame Shift Del (DEL) | VAF 103/290 reads (36%) | called by mutect2, pindel, varscan2
- KALRN | c.1375A>C p.T459P | Missense Mutation (SNP) | VAF 79/475 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- KCNJ15 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 330/663 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- KCNN4 | c.792G>C p.K264N | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KEAP1 | c.1187dup p.Y396* | Nonsense Mutation (INS) | VAF 502/701 reads (72%) | called by mutect2, pindel, varscan2
- KIAA0825 | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 196/405 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF3A | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 268/548 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KLHL32 | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KMT2B | c.3488A>G p.K1163R | Missense Mutation (SNP) | VAF 25/336 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); called by muse, mutect2
- LMOD3 | c.1338C>G p.F446L | Missense Mutation (SNP) | VAF 351/684 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPCAT1 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 280/615 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC39 | c.739C>G p.L247V | Missense Mutation (SNP) | VAF 110/387 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC8C | c.2171A>G p.E724G | Missense Mutation (SNP) | VAF 245/374 reads (66%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- LRRIQ3 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 97/158 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MAGI3 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 233/353 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MAP7D2 | c.2038A>G p.T680A | Missense Mutation (SNP) | VAF 252/252 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- METTL27 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 28/704 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.08); called by muse, mutect2
- MLLT10 | c.2867G>A p.G956E (on ENST00000307729 / NM_001195626.3; = p.G972E on NM_004641.3) | Missense Mutation (SNP) | VAF 186/311 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUGGC | c.1902C>G p.I634M | Missense Mutation (SNP) | VAF 198/364 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- NUP210L | c.3792G>C p.M1264I | Missense Mutation (SNP) | VAF 30/697 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- OPA1 | c.2911G>T p.D971Y (on ENST00000361510 / NM_130837.3; = p.D916Y on NM_015560.3) | Missense Mutation (SNP) | VAF 193/420 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR12D3 | c.651C>G p.F217L | Missense Mutation (SNP) | VAF 374/588 reads (64%) | SIFT tolerated (0.93); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR5H2 | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 322/636 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PALB2 | c.2195G>A p.G732D | Missense Mutation (SNP) | VAF 161/505 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB14 | c.1592T>C p.V531A | Missense Mutation (SNP) | VAF 525/1106 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PCDHB8 | c.1204T>C p.Y402H | Missense Mutation (SNP) | VAF 326/2185 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- PCDHGC4 | c.919C>A p.P307T | Missense Mutation (SNP) | VAF 26/739 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.042); called by muse, mutect2
- PLA2G7 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 93/299 reads (31%) | called by muse, mutect2, varscan2
- PRKAR1B | c.563G>C p.G188A | Missense Mutation (SNP) | VAF 207/426 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PRRT3 | c.2554del p.R852Gfs*37 | Frame Shift Del (DEL) | VAF 429/992 reads (43%) | called by mutect2, pindel, varscan2
- RSF1 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 206/607 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RYR3 | c.14337G>C p.Q4779H (on ENST00000389232; = p.Q4780H on NM_001036.6) | Missense Mutation (SNP) | VAF 201/262 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A41 | c.297_325del p.A100Hfs*53 | Frame Shift Del (DEL) | VAF 144/156 reads (92%) | called by mutect2, pindel, varscan2
- SPATA6 | c.1295A>C p.Q432P | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.926); called by muse, mutect2
- SVEP1 | c.3273A>C p.E1091D | Missense Mutation (SNP) | VAF 13/416 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2
- TBL1Y | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 93/276 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCEANC | c.535G>C p.E179Q (on ENST00000380600 / NM_001297563.2; = p.E209Q on NM_152634.4) | Missense Mutation (SNP) | VAF 338/339 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- TIAM2 | c.731G>C p.S244T | Missense Mutation (SNP) | VAF 169/501 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TICRR | c.2167G>T p.V723L | Missense Mutation (SNP) | VAF 247/354 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- TMEM121 | c.17C>G p.P6R | Missense Mutation (SNP) | VAF 151/436 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMPRSS5 | c.989C>G p.P330R | Missense Mutation (SNP) | VAF 250/391 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNIK | c.2977G>C p.D993H | Missense Mutation (SNP) | VAF 170/356 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TNIK | c.1976G>A p.S659N | Missense Mutation (SNP) | VAF 206/405 reads (51%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- TPD52L1 | c.228G>A p.M76I | Missense Mutation (SNP) | VAF 121/356 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TRAF3IP3 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 134/584 reads (23%) | called by muse, mutect2, varscan2
- TRIM51 | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TRIP13 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 224/478 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TTC3 | c.1266dup p.D423* | Frame Shift Ins (INS) | VAF 172/457 reads (38%) | called by mutect2, pindel, varscan2
- VAT1L | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 145/224 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WNT10A | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 374/765 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- WNT9B | c.167A>G p.D56G | Missense Mutation (SNP) | VAF 482/991 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- XPR1 | c.294G>C p.Q98H | Missense Mutation (SNP) | VAF 127/583 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- ZGPAT | c.158G>T p.S53I | Missense Mutation (SNP) | VAF 345/694 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF189 | c.1205G>T p.C402F | Missense Mutation (SNP) | VAF 113/434 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC099489.1 | c.3138C>A p.I1046= | Silent (SNP) | VAF 93/245 reads (38%) | catalogued as rs948638746; called by muse, mutect2, varscan2
- ARHGAP23 | c.4221C>T p.T1407= | Silent (SNP) | VAF 363/768 reads (47%) | called by muse, mutect2, varscan2
- ATN1 | c.2352C>T p.F784= | Silent (SNP) | VAF 358/1041 reads (34%) | catalogued as rs1418627045, COSV100755921, COSV63112947; called by muse, mutect2, varscan2
- AVL9 | c.1014C>G p.V338= | Silent (SNP) | VAF 84/549 reads (15%) | called by muse, mutect2, varscan2
- BHMG1 | c.1104C>T p.F368= | Silent (SNP) | VAF 337/339 reads (99%) | catalogued as COSV71837285; called by muse, mutect2, varscan2
- CAMK1D | c.687C>A p.L229= | Silent (SNP) | VAF 139/435 reads (32%) | called by muse, mutect2, varscan2
- CD244 | c.363C>T p.F121= | Silent (SNP) | VAF 110/506 reads (22%) | catalogued as rs774752476, COSV59241003; called by muse, varscan2
- CDK5RAP3 | c.225C>G p.L75= | Silent (SNP) | VAF 227/506 reads (45%) | called by muse, mutect2, varscan2
- CLIP2 | c.540G>T p.L180= | Silent (SNP) | VAF 340/733 reads (46%) | catalogued as COSV56285477; called by muse, mutect2, varscan2
- CLIP2 | c.2391C>T p.V797= | Silent (SNP) | VAF 206/445 reads (46%) | catalogued as rs1298881144; called by muse, mutect2, varscan2
- CSMD2 | c.2469C>T p.H823= | Silent (SNP) | VAF 268/417 reads (64%) | catalogued as rs774509837, COSV53969756; called by muse, mutect2, varscan2
- CYP11A1 | c.1077G>A p.A359= | Silent (SNP) | VAF 172/549 reads (31%) | catalogued as rs987318812, COSV51431482; called by muse, mutect2, varscan2
- CYP2S1 | c.888C>T p.V296= | Silent (SNP) | VAF 276/293 reads (94%) | called by muse, mutect2, varscan2
- DOCK2 | c.1464C>G p.R488= | Silent (SNP) | VAF 254/512 reads (50%) | called by muse, mutect2, varscan2
- EFNA4 | c.576T>C p.L192= | Silent (SNP) | VAF 187/771 reads (24%) | catalogued as rs202221214; called by muse, mutect2, varscan2
- EHD3 | c.1011G>A p.E337= | Silent (SNP) | VAF 309/625 reads (49%) | called by muse, mutect2, varscan2
- FAM209A | c.240G>A p.E80= | Silent (SNP) | VAF 172/370 reads (46%) | called by muse, varscan2
- FAT3 | c.8088C>A p.I2696= | Silent (SNP) | VAF 256/395 reads (65%) | called by muse, mutect2, varscan2
- GEMIN4 | c.2334C>T p.F778= | Silent (SNP) | VAF 363/363 reads (100%) | catalogued as rs1451608184; called by muse, mutect2, varscan2
- H2AX | c.381G>A p.P127= | Silent (SNP) | VAF 181/508 reads (36%) | called by muse, mutect2, varscan2
- HSF1 | c.57G>A p.L19= | Silent (SNP) | VAF 273/556 reads (49%) | catalogued as rs782766056; called by muse, mutect2, varscan2
- INSRR | c.3633G>T p.L1211= | Silent (SNP) | VAF 113/807 reads (14%) | called by muse, mutect2, varscan2
- IRX1 | c.975C>T p.S325= | Silent (SNP) | VAF 359/807 reads (44%) | called by muse, mutect2, varscan2
- KHDC1 | c.54C>T p.V18= | Silent (SNP) | VAF 213/357 reads (60%) | called by muse, mutect2, varscan2
- KLF18 | c.3006G>A p.T1002= | Silent (SNP) | VAF 198/298 reads (66%) | catalogued as rs540006283; called by muse, varscan2
- LGR6 | c.1356G>A p.G452= (on ENST00000367278 / NM_001017403.1; = p.G400= on NM_021636.3) | Silent (SNP) | VAF 96/473 reads (20%) | called by muse, mutect2, varscan2
- LRRC14B | c.1362C>A p.I454= | Silent (SNP) | VAF 347/703 reads (49%) | called by muse, mutect2, varscan2
- MRPL24 | c.171C>T p.F57= | Silent (SNP) | VAF 266/840 reads (32%) | called by muse, mutect2, varscan2
- MYH13 | c.5604C>A p.L1868= | Silent (SNP) | VAF 10/233 reads (4%) | called by muse, mutect2
- NEB | c.14832C>G p.L4944= | Silent (SNP) | VAF 192/384 reads (50%) | called by muse, mutect2, varscan2
- NUP210 | c.2922C>T p.Y974= | Silent (SNP) | VAF 245/483 reads (51%) | catalogued as rs553918791; called by muse, mutect2, varscan2
- OR1N2 | c.429C>T p.L143= | Silent (SNP) | VAF 272/411 reads (66%) | called by muse, mutect2, varscan2
- OR4C12 | c.787C>T p.L263= | Silent (SNP) | VAF 125/420 reads (30%) | catalogued as rs782526433; called by muse, mutect2, varscan2
- OR5M8 | c.51C>T p.T17= | Silent (SNP) | VAF 131/394 reads (33%) | called by muse, mutect2, varscan2
- P2RX2 | c.141C>T p.A47= | Silent (SNP) | VAF 277/638 reads (43%) | catalogued as rs760417852, COSV57684404; called by muse, mutect2, varscan2
- PGAP3 | c.792G>A p.Q264= | Silent (SNP) | VAF 359/740 reads (49%) | catalogued as rs1477897371; called by muse, mutect2, varscan2
- PGK2 | c.219T>G p.P73= | Silent (SNP) | VAF 134/453 reads (30%) | called by muse, mutect2, varscan2
- RIMS4 | c.42C>T p.F14= | Silent (SNP) | VAF 184/368 reads (50%) | catalogued as rs1014665258, COSV65719322, COSV65719408; called by muse, mutect2, varscan2
- RNF213 | c.2913C>G p.L971= | Silent (SNP) | VAF 203/443 reads (46%) | called by muse, mutect2, varscan2
- SACM1L | c.264A>G p.V88= | Silent (SNP) | VAF 197/404 reads (49%) | called by muse, mutect2, varscan2
- SPRED2 | c.762C>T p.F254= | Silent (SNP) | VAF 391/885 reads (44%) | catalogued as rs749770464; called by muse, mutect2, varscan2
- SPTBN5 | c.5208G>A p.L1736= | Silent (SNP) | VAF 190/656 reads (29%) | called by muse, mutect2
- SYNE2 | c.16653G>A p.L5551= | Silent (SNP) | VAF 256/391 reads (65%) | catalogued as COSV59943643; called by muse, mutect2, varscan2
- TEDC1 | c.282G>C p.L94= | Silent (SNP) | VAF 63/549 reads (11%) | called by muse, mutect2, varscan2
- THRB | c.472C>A p.R158= | Silent (SNP) | VAF 230/516 reads (45%) | called by muse, mutect2, varscan2
- UNC13C | c.3210C>A p.S1070= | Silent (SNP) | VAF 81/324 reads (25%) | called by mutect2, varscan2
- VIL1 | c.2277C>T p.L759= | Silent (SNP) | VAF 284/598 reads (47%) | catalogued as COSV50288138; called by muse, mutect2, varscan2
- WRAP73 | c.486C>T p.I162= | Silent (SNP) | VAF 205/322 reads (64%) | catalogued as rs760371845; called by muse, mutect2, varscan2
- ZNF687 | c.2916C>T p.F972= | Silent (SNP) | VAF 175/695 reads (25%) | catalogued as rs1283947640; called by muse, mutect2, varscan2
- ATXN7 | c.*64C>T | 3'UTR (SNP) | VAF 189/410 reads (46%) | called by muse, mutect2, varscan2
- CD300LD | c.40+39C>T | Intron (SNP) | VAF 196/365 reads (54%) | catalogued as rs916785764, COSV60084414; called by muse, mutect2, varscan2
- CRELD1 | c.1049-401C>T | Intron (SNP) | VAF 238/525 reads (45%) | called by muse, mutect2, varscan2
- NPC2 | chr14:74476590 C>T | 3'Flank (SNP) | VAF 69/224 reads (31%) | called by muse, mutect2, varscan2
- RAF1 | c.834+621C>T | Intron (SNP) | VAF 240/493 reads (49%) | called by muse, mutect2, varscan2
- RCOR3 | chr1:211259572 G>C | 5'Flank (SNP) | VAF 226/494 reads (46%) | called by muse, mutect2, varscan2
- RGS6 | c.1368+5284C>T | Intron (SNP) | VAF 21/513 reads (4%) | called by muse, mutect2
- SRGAP2 | c.2358-723G>T | Intron (SNP) | VAF 224/472 reads (47%) | called by muse, mutect2, varscan2
